CCDI case PBCFPI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a6ff7e69-e483-479b-a90a-95a5f75c4328

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 7.0 years (2,550 days).

Biospecimens (3 samples)
- Sample 0DR9BN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR9C2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DR9CO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
